Somatic mutation profile of tumor specimen 0DMKL1 from CCDI case PBBZWB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 8.3 years (3,018 days).
Specimen 0DMKL1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69ca3e85-a408-4c0c-a8cc-34a7e203a85f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fcc0e11-66e3-467b-a495-1a6fdd7c6990

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 4, Nonsense Mutation 2, 3'UTR 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 602/1328 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV66065276; called by muse, varscan2
- KRTAP2-2 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as rs1300239928; called by muse, varscan2
- LRIG3 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 108/1000 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758945528; called by muse, varscan2
- NSD1 | c.4967G>T p.G1656V | Missense Mutation (SNP) | VAF 70/559 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61770598; called by muse, varscan2
- PIGT | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 108/966 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.778); catalogued as rs143235179; called by muse, varscan2
- PROS1 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 108/520 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV62397576, COSV62399997; called by muse, varscan2
- ABCA12 | c.7493A>G p.E2498G (on ENST00000272895 / NM_173076.3; = p.E2180G on NM_015657.3) | Missense Mutation (SNP) | VAF 116/961 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, varscan2
- BRWD3 | c.4405G>A p.G1469R | Missense Mutation (SNP) | VAF 147/337 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, varscan2
- CMYA5 | c.6892T>A p.S2298T | Missense Mutation (SNP) | VAF 114/911 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); called by muse, varscan2
- CYLC2 | c.655A>G p.K219E | Missense Mutation (SNP) | VAF 424/1924 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.163); called by muse, varscan2
- EVI2B | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 249/2160 reads (12%) | called by muse, varscan2
- KLHDC9 | c.842G>C p.R281T | Missense Mutation (SNP) | VAF 260/1016 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); called by muse, varscan2
- LINS1 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 197/960 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, varscan2
- MESP2 | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 364/768 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPAT | c.1014G>C p.K338N | Missense Mutation (SNP) | VAF 138/837 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, varscan2
- PPFIA1 | c.1667A>T p.Q556L | Missense Mutation (SNP) | VAF 185/648 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, varscan2
- RBMY1E | c.1313G>C p.C438S | Missense Mutation (SNP) | VAF 186/1278 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- SFTPC | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 242/1283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SGCE | c.573C>T p.D191= (on ENST00000647096; = p.D155= on NM_003919.3) | Splice Region (SNP) | VAF 365/868 reads (42%) | called by muse, varscan2
- STXBP4 | c.350A>T p.N117I | Missense Mutation (SNP) | VAF 548/2039 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); called by muse, varscan2
- THADA | c.3652T>C p.F1218L | Missense Mutation (SNP) | VAF 134/633 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, varscan2
- USH2A | c.6418C>T p.Q2140* | Nonsense Mutation (SNP) | VAF 112/1038 reads (11%) | called by muse, varscan2
- WFIKKN2 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 386/1671 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.259); called by muse, varscan2
- XPNPEP3 | c.1331C>G p.P444R | Missense Mutation (SNP) | VAF 522/1142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ADAMTSL1 | c.3579C>T p.S1193= | Silent (SNP) | VAF 246/538 reads (46%) | catalogued as rs1308514281, COSV65893753; called by muse, varscan2
- CEACAM5 | c.912A>C p.S304= | Silent (SNP) | VAF 132/1026 reads (13%) | called by muse, varscan2
- HMCN2 | c.14013C>T p.D4671= | Silent (SNP) | VAF 89/418 reads (21%) | catalogued as rs752861799; called by muse, varscan2
- IMPG1 | c.750G>A p.E250= | Silent (SNP) | VAF 200/1758 reads (11%) | called by muse, varscan2
- MAGEE1 | c.1599C>G p.L533= | Silent (SNP) | VAF 124/512 reads (24%) | called by muse, varscan2
- NUMB | c.711A>G p.P237= (on ENST00000355058; = p.P226= on NM_003744.5) | Silent (SNP) | VAF 230/570 reads (40%) | called by muse, varscan2
- RAB23 | c.96C>T p.G32= | Silent (SNP) | VAF 208/1649 reads (13%) | catalogued as rs571935782; called by muse, varscan2
- RAVER2 | c.15G>C p.A5= | Silent (SNP) | VAF 116/497 reads (23%) | called by muse, varscan2
- LARP4 | c.18+1693A>T | Intron (SNP) | VAF 127/304 reads (42%) | called by muse, varscan2
- MTMR4 | c.*95C>A | 3'UTR (SNP) | VAF 162/473 reads (34%) | called by muse, varscan2
- MYO1G | c.1504-34C>G | Intron (SNP) | VAF 334/472 reads (71%) | called by muse, varscan2
- OPRPN | c.*23C>A | 3'UTR (SNP) | VAF 223/551 reads (40%) | called by muse, varscan2
- RAB11B | c.236+14G>A | Intron (SNP) | VAF 68/706 reads (10%) | called by muse, varscan2
- SUPT20H | c.1211+94A>G | Intron (SNP) | VAF 62/216 reads (29%) | called by muse, varscan2
- VSTM2A | c.-73T>G | 5'UTR (SNP) | VAF 22/210 reads (10%) | called by muse, varscan2
